Somatic mutation profile of tumor specimen TCGA-HG-A9SC-01A (aliquot TCGA-HG-A9SC-01A-21D-A42O-09) from TCGA case TCGA-HG-A9SC, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenosquamous carcinoma; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 49.2 years (17,963 days).
Specimen TCGA-HG-A9SC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f253bb7-fe4a-49b1-bf5f-58fcd99cc5b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HG-A9SC-10A (Blood Derived Normal), aliquot TCGA-HG-A9SC-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c4f49ef-7079-4768-b91b-3a1a3a7404c6

The open-access MAF lists 85 somatic variants for this specimen: 71 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 11, Nonsense Mutation 6, In Frame Del 3, Frame Shift Ins 2, 5'UTR 1, Intron 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AEN | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs139013526, COSV60430715; called by muse, mutect2, varscan2
- ARHGEF10 | c.2890C>T p.P964S (on ENST00000398564; = p.P939S on NM_014629.4) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1388535784, COSV100035038; called by muse, mutect2, varscan2
- ATP10A | c.4373G>A p.R1458Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); catalogued as rs201372264; called by muse, mutect2, varscan2
- ATP2A3 | c.1064C>T p.T355M | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1423420491, COSV99989442; called by muse, mutect2
- BBS12 | c.653A>C p.N218T | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs78174492, COSV100045032; called by muse, mutect2, varscan2
- BLM | c.2411G>T p.G804V | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100757270; called by muse, mutect2
- CBX4 | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as COSV99490450; called by muse, mutect2, varscan2
- CCDC144A | c.1557_1559del p.E519del | In Frame Del (DEL) | VAF 52/196 reads (27%) | catalogued as rs749083042; called by pindel, varscan2
- CREBBP | c.2411G>T p.G804V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99270986; called by muse, mutect2, varscan2
- CXCR4 | c.712C>T p.L238F | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1256938467, COSV99603259; called by muse, mutect2, varscan2
- CXorf21 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV100973329; called by muse, mutect2, varscan2
- DCAF12L2 | c.616A>C p.T206P | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV100758724; called by muse, mutect2, varscan2
- DGKI | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.691); catalogued as rs148415050; called by muse, mutect2, varscan2
- DHDH | c.228C>A p.H76Q | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99668568; called by muse, mutect2, varscan2
- DNAJC5G | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV99940611; called by muse, mutect2, varscan2
- DNAL4 | c.27T>A p.D9E | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV99326158; called by muse, varscan2
- ELMO2 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.59); catalogued as rs924016543, COSV51682599; called by muse, mutect2, varscan2
- ESRP1 | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as COSV100619465; called by muse, mutect2, varscan2
- FAT1 | c.10499C>G p.S3500* | Nonsense Mutation (SNP) | VAF 40/68 reads (59%) | catalogued as COSV101499482, COSV71674329; called by muse, mutect2, varscan2
- FES | c.1882C>T p.Q628* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100183224; called by muse, mutect2, varscan2
- GCNT3 | c.1253A>G p.D418G | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.591); catalogued as COSV101251853; called by muse, mutect2, varscan2
- GNAL | c.277A>C p.I93L (on ENST00000269162 / NM_001142339.3; = p.I170L on NM_182978.4) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.808); catalogued as COSV99303933; called by muse, mutect2, varscan2
- GRM7 | c.323C>A p.T108N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100737509; called by muse, mutect2, varscan2
- HNRNPH1 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100271113, COSV61489632; called by muse, mutect2
- HSPB7 | c.421C>G p.L141V | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100318004; called by muse, mutect2, varscan2
- KCTD14 | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100779936; called by muse, varscan2
- KIAA1549L | c.3307C>T p.R1103W (on ENST00000321505; = p.R1400W on NM_012194.3) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747515119, COSV55769669; called by muse, mutect2, varscan2
- KLHL17 | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs150067459; called by muse, mutect2, varscan2
- MAPK4 | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV68542296; called by muse, mutect2, varscan2
- MED25 | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759187460, COSV57205114; called by muse, mutect2
- MELTF | c.1436G>C p.G479A | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.253); catalogued as COSV99586392; called by muse, mutect2
- MOV10 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs772510801, COSV100659678; called by muse, mutect2, varscan2
- MX1 | c.1619G>A p.G540D | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.71); PolyPhen benign (0.175); catalogued as COSV55818293; called by muse, mutect2, varscan2
- MYLK4 | c.1021C>T p.L341F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51145061; called by muse, mutect2, varscan2
- NOTCH1 | c.3226C>T p.Q1076* | Nonsense Mutation (SNP) | VAF 50/64 reads (78%) | catalogued as COSV99490017; called by muse, mutect2, varscan2
- NOTCH3 | c.2142C>T p.G714= | Splice Region (SNP) | VAF 13/25 reads (52%) | catalogued as rs369579579, COSV99658134; called by muse, varscan2
- OCRL | c.1094A>G p.H365R | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as COSV100843507; called by muse, mutect2, varscan2
- OR5H2 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs757790420, COSV62350692; called by muse, mutect2, varscan2
- PCDHA2 | c.71G>C p.W24S | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.072); catalogued as rs1281191089, COSV100974052, COSV65364864; called by muse, mutect2, varscan2
- PER3 | c.2315C>T p.P772L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as rs148764781; called by muse, varscan2
- POLN | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV101242617; called by muse, mutect2, varscan2
- PORCN | c.781C>T p.L261F (on ENST00000326194 / NM_203475.3; = p.L250F on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV58227324; called by muse, mutect2, varscan2
- POT1 | c.1711T>A p.S571T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.787); catalogued as COSV100714103; called by muse, mutect2, varscan2
- POTEH | c.508T>G p.Y170D | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100625104, COSV58887546; called by muse, mutect2, varscan2
- RFX7 | c.1141A>G p.I381V (on ENST00000559447 / NM_001368074.1; = p.I478V on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.108); catalogued as rs756390978, COSV100429092; called by muse, mutect2, varscan2
- RSC1A1 | c.1097G>A p.S366N | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1324563089, COSV100197790, COSV60779712; called by muse, mutect2, varscan2
- RUBCNL | c.1298T>C p.F433S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV100529261; called by muse, mutect2, varscan2
- SDCCAG8 | c.1870C>T p.L624F | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as COSV100654456; called by muse, mutect2, varscan2
- SLC35G6 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs772915658, COSV59493287; called by muse, mutect2, varscan2
- SYNE2 | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV100420305; called by muse, mutect2, varscan2
- SYTL4 | c.638C>G p.S213C | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.706); catalogued as COSV99343119; called by muse, mutect2, varscan2
- TACR2 | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs200445225, COSV64822157; called by muse, mutect2, varscan2
- TBX3 | c.2188G>A p.G730S (on ENST00000257566 / NM_016569.4; = p.G710S on NM_005996.4) | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1407667924, COSV99983957; called by muse, mutect2, varscan2
- TEAD2 | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100246675; called by muse, mutect2, varscan2
- TMEM63B | c.2495A>C p.Q832P | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.193); catalogued as COSV99441864; called by muse, mutect2, varscan2
- TOP2A | c.53T>A p.I18K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV101396305; called by muse, mutect2, varscan2
- TTLL7 | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.225); catalogued as COSV99552768; called by muse, mutect2, varscan2
- TTN | c.59993G>A p.R19998Q (on ENST00000591111; = p.R12574Q on NM_003319.4) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | PolyPhen probably damaging (0.996); catalogued as rs373282633, COSV60180849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC93B1 | c.1710G>C p.R570S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV99916467; called by muse, mutect2, varscan2
- USP11 | c.2317G>A p.V773M (on ENST00000218348; = p.V730M on NM_001371072.1) | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs1389270745, COSV54475673; called by muse, mutect2, varscan2
- WDR13 | c.1048G>T p.E350* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | catalogued as COSV99489511; called by muse, mutect2, varscan2
- ZFHX4 | c.1928C>T p.T643I | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99265429; called by muse, mutect2
- ZNF479 | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV100482902; called by muse, mutect2, varscan2
- ZNF549 | c.1566C>G p.I522M (on ENST00000376233 / NM_001199295.2; = p.I509M on NM_153263.2) | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV99558678; called by muse, mutect2, varscan2
- ZNF85 | c.815C>A p.T272N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.029); catalogued as COSV100059984; called by muse, mutect2, varscan2
- CDC73 | c.1202_1207del p.N401_E402del | In Frame Del (DEL) | VAF 30/117 reads (26%) | called by mutect2, pindel, varscan2
- DST | c.7320_7328del p.S2442_A2444del | In Frame Del (DEL) | VAF 13/51 reads (25%) | called by mutect2, pindel, varscan2
- FOXD4L4 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.104); called by mutect2, varscan2
- KIAA0100 | c.6245C>A p.T2082N | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- LRRN1 | c.2014dup p.T672Nfs*8 | Frame Shift Ins (INS) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- PDE1B | c.84dup p.K29Qfs*6 | Frame Shift Ins (INS) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- ADGRB1 | c.3009C>A p.T1003= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100030024; called by muse, varscan2
- ATXN2L | c.819T>C p.S273= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV100294819; called by muse, mutect2, varscan2
- CDHR5 | c.2187C>T p.D729= (on ENST00000358353 / NM_001171968.2; = p.D735= on NM_021924.5) | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV100363697; called by muse, mutect2, varscan2
- CPSF3 | c.813A>G p.A271= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV99433044; called by muse, mutect2, varscan2
- FNIP2 | c.1563G>T p.L521= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100033078, COSV100033450; called by muse, mutect2, varscan2
- GMIP | c.840G>A p.A280= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV52559224; called by muse, mutect2
- LAMB4 | c.4683A>G p.K1561= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as COSV99224917; called by muse, mutect2, varscan2
- LTN1 | c.1782C>T p.V594= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV100798078; called by muse, mutect2, varscan2
- SNX29 | c.2349C>T p.N783= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs1171395797, COSV100029523; called by muse, mutect2
- USH2A | c.8115T>C p.L2705= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV100238889; called by muse, mutect2, varscan2
- XIRP2 | c.4584T>A p.I1528= (on ENST00000628543; = p.I1703= on NM_152381.6) | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV99745439, COSV99746527; called by muse, mutect2, varscan2
- HERC2P3 | n.1810C>T | RNA (SNP) | VAF 5/33 reads (15%) | called by mutect2, varscan2
- RUNX2 | c.-268C>A | 5'UTR (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100177709; called by muse, mutect2, varscan2
- ZNF783 | c.802+3315C>T | Intron (SNP) | VAF 14/33 reads (42%) | catalogued as rs751038122, COSV100954274; called by muse, varscan2
